Surgical pathology report (de-identified scan), TCGA case TCGA-29-2433, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2433-01A (Primary Tumor).

[page 1 of 3]
Surg Path

CLINICAL HISTORY:

Abdominal and pelvic swelling NOS = 789.30.

GROSS EXAMINATION:

A. "Omentum (AF1)", received unfixed for frozen section is a 238 gram, 16.4 x 12.5 x 2.2 cm portion of yellow, lobulated adipose tissue. The specimen is remarkable for multiple firm nodules up to 7 cm in greatest dimension. Sectioning through the nodules demonstrates a firm, tan-white cut surface. A representative section is submitted for frozen section as AF1. The remainder of the specimen is grossly unremarkable. Further representative sections are submitted in blocks A2-4.

B. "Left tube and ovary", received unfixed is a 26 gram, 5 x 3.5 x 2 cm ovary with contiguous 5 cm portion of fallopian tube which the ovarian serosal surface is remarkable for multiple, firm, tan papillary excrescences that appear to extend through the capsule up to 1.5 cm in greatest dimension. Sectioning through the ovary demonstrates a 2 x 2 x 1.8 cm cyst with focal septations containing multiple soft tan excrescences. There is an additional 1.8 x 1.8 x 1.6 cm multiloculated cyst involving the remainder of the ovarian parenchyma. Again, there are multiple soft tan lined excrescences present within the cyst. No grossly identifiable ovary is present. Sectioning through the adjacent fallopian tube demonstrates an average diameter of 0.4 cm. No gross lesions are identified. Representative sections of ovary are submitted in blocks B1-4 with fallopian tube in block B4.

C. "Right tube and ovary", received unfixed is a 100 gram, 7.5 x 6.5 x 5.5 cm ovary with a contiguous 5 cm portion of fimbriated fallopian tube. The serosal surface is remarkable for multiple previously disrupted cysts up to 6 cm in greatest dimension. The cysts are remarkable for a thickened capsule with multiple tan-white excrescences. The serosal surface is also remarkable for a bulging soft, tan-white mass that largely replaces the ovarian cut surface, 6 x 5 x 3.6 cm. There are focal areas of hemorrhage and necrosis within the mass. The adjacent fallopian tube demonstrates a grossly unremarkable cut surface with an average diameter of 0.5 cm. Within the mesosalpinx, there is a single 0.3 x 0.2 x 0.2 cm tan-white excrescence.

BLOCK SUMMARY:

- C1- largest cyst with excrescences
- C2-6- representative sections of mass
- C7- fallopian tube

D. "Cul-de-sac nodule", received unfixed is a 3 x 2.5 x 0.7 cm aggregate of tan-brown tissue. The specimen is sectioned and submitted in blocks D1-2.

E. "Nodule from right diaphragm", received unfixed is a 3 x 2.5 x 0.6 cm aggregate of tan-brown tissue. The specimen is submitted entirely in blocks E1-2.

INTRA OPERATIVE CONSULTATION:

- A. "Omentum": AF1- (representative nodules)- poorly differentiated carcinoma (

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

[page 2 of 3]
IMMUNOHISTOCHEMICAL FINDINGS:

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the Immunopathology Laboratory,

the U.S. Food and Drug Administration. Some of them may not be cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

PATHOLOGIC STAGE:

PROCEDURE: SALPINGO-OOPHORECTOMY AND PARTIAL OMENTECTOMY

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM (AF1)":

ADIPOSE TISSUE WITH POORLY DIFFERENTIATED ADENOCARCINOMA, SEE COMMENT.
MAXIMUM TUMOR SIZE: 7 CM.

B. "LEFT TUBE AND OVARY":

OVARY:

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 3.

TUMOR SIZE: 5 X 3.5 CM.

WEIGHT: 26 GRAMS

SEROSA: POSITIVE FOR TUMOR.

ADDITIONAL FINDINGS: FALLOPIAN TUBE, NEGATIVE FOR CARCINOMA.

C. "RIGHT TUBE AND OVARY":

OVARY:

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 3.

TUMOR SIZE: 7.5 X 6.5 X 5.5 CM.

WEIGHT: 100 GRAMS

SEROSA: POSITIVE FOR CARCINOMA.

ADDITIONAL FINDINGS: FALLOPIAN TUBE, POSITIVE FOR CARCINOMA.

D. "CUL-DE-SAC NODULE":

POORLY DIFFERENTIATED ADENOCARCINOMA.
MAXIMUM TUMOR SIZE: 2.5 CM.

E. "NODULE FROM RIGHT DIAPHRAGM":

POORLY DIFFERENTIATED ADENOCARCINOMA.
MAXIMUM TUMOR SIZE: 2.5 CM.

COMMENT: The tumor is very poorly differentiated, but does show definite

[page 3 of 3]
areas of glandular differentiation. Focally, there is the suggestion of papillary differentiation. Immunostains of the tumor on block C2 are positive for cytokeratin 7, Berp4, are focally positive for CA125, and are negative for TTF1, CDX2, CK20, WT1, and calretinin. The combination of the immunohistologic pattern and routine light microscopic appearance of the tumor is most consistent with a primary tumor of the ovary, very poorly differentiated serous type.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file a1ef1cd4-3cfc-4006-8d2d-7ffb98ed0805 (TCGA-29-2433.A7C12225-FECB-496D-AD8E-40C7504128EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).